Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AACP, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AACP-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: HCC

Specimen : HCC--liver

Gross Photo :

GROSS:

Specimen:

Liver: 4.5 x 4.5 x 3.5 and 45.5 gm, unfixed

Gallbladder: 8.5 cm in length and 4.0 cm in diameter, unfixed

Tumor location: segment 5

Tumor number: one

Tumor size: 3.3 x 3.1 x 3.0 cm

Satellite nodule: no

Gross type

HCC: pedunculated type

Tumor necrosis: no

Hemorrhage/peliosis: yes (10 %)

Portal vein invasion: no

Bile duct invasion: no

Other organ:

Gallbladder: Unremarkable (0.2 cm in wall thickness)

Gross photo present.

Blocks

T1-4, mass with liver parenchyma x 4

RM, resection margin x 1

GB, gallbladder x 1

MICROSCOPIC:

Hepatocellular carcinoma: yes

Differentiation

The worst differentiation III

The major differentiation II

Histologic type: trabecular

Cell type: hepatic

Fatty change: no

Cholangiocarcinoma: no

Combined hepatocellular and cholangiocarcinoma: no

Other tumor: no

Fibrous capsule formation: complete capsule

Capsular infiltration: no

Septum formation: yes

ICD O-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver C22.0

Q4 5/19/14

[page 2 of 2]
Surgical resection margin invasion: no, margin of the clearance (0.4 cm)
Serosal invasion: no
Portal vein invasion: no
Bile duct invasion: no
Hepatic vein invasion: no
Hepatic artery invasion: no
Microvessel invasion: no
Intrahepatic metastasis: no
Multicentric occurrence: no
Non-tumor liver pathology: micronodular cirrhosis

NOT reported. Gross:

NOT reported. Gross:

Stomach, body,antrum, scopic, hyperplastic polyp
Stomach, antrum, scopic, tubular adenoma, high grade, dysplasia

Stomach, antrum, dissection, tubular adenoma, high grade, dysplasia

liver,needle,hepatocellular carcinoma,cirrhosis

Liver, resection, hepatocellular carcinoma
T56000, P17, M81703
Gallbladder, ectomy, chronic cholecystitis
T57000, P10, M43005

DIAGNOSIS:
Liver, segment 5, resection:
Hepatocellular carcinoma

Gallbladder, cholecystectomy:
Chronic cholecystitis, no tumor present

Suggestion :

Source: NCI Genomic Data Commons file b397df7f-d8c1-4936-be27-d91b211c28a0 (TCGA-DD-AACP.7FDD120A-A5AD-4209-B167-34BA2289A784.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).